Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H8-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. LIVER, RIGHT LOBE, SEGMENTAL RESECTION AND EN BLOC RESECTION OF LIVER TUMOR AND GALLBLADDER:
Hepatocellular carcinoma, moderately differentiated.
See Key Pathological Findings.
Tumor necrosis: present (5%)
Gallbladder: Mild chronic cholecystitis.

I, _____, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by :

Comment

The tumor cells are positive for AFP and HepPart by immunohistochemistry. The CEA immunostain is also positive and exhibits a canalicular pattern of staining. These results support the above diagnosis. The stains were performed with appropriate controls on block A2.

Key Pathological Findings

A: Liver, Resection

Specimen:

Liver

Gallbladder

PROCEDURE:

Partial hepatectomy

*Minor hepatectomy (less than 3 segments)

TUMOR SIZE:

Greatest dimension: 8 cm

*Additional dimensions: 6.5 X 6.5 cm

TUMOR FOCALITY:

Solitary (specify location): Right Lobe

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

ICD-8-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
J 4/28/14

[page 2 of 2]
PMX: Cannot be assessed

MARGINS:
Parenchymal margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 7 mm

***VENOUS (LARGE VESSEL) INVASION (V):**
*Present

***ADDITIONAL PATHOLOGIC FINDINGS:**
*Cirrhosis/fibrosis

Specimen(s) Received

A SEGMENTAL RESECTION RIGHT LOBE LIVER WITH EN BLOC RESECTION OF LIVER TUMOR AND GALLBLADDER

Clinical History

LIVER CANCER

Intraoperative Consultation

A. GROSS:
Inked margin is free of tumor.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by _____ at _____

I, _____, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh for intraoperative consultations labeled with the patient's name and designated "segmental resection, right lobe liver and en bloc resection of liver tumor and gallbladder." The specimen consists of a portion of liver tissue attached with gallbladder. The liver measures 10 x 9 x 9 cm; the gallbladder measures 8 x 2.5 x 2.5 cm. The surgical resection margin of the liver is inked blue. The external surface of the liver is mostly smooth, but with focal nodular area. On sectioning, there is a tumor measuring 8 x 6.5 x 6.5 cm. The tumor is well circumscribed. The cut surface of the tumor is gray to pink with multilobulated appearance. Necrosis and hemorrhage are present. In the center of the tumor there is a stellate scar. The tumor is 0.7 cm from the closest parenchymal surgical resection margin. It is subcapsular, and comes within 0.1 cm from the overlying capsule. The serosal surface of the gallbladder is smooth and glistening. The cystic wall measures 0.1 cm in thickness. The mucosal surface is velvety and bile-tinged. There is medium amount of bile, and no calculi are identified. One section is submitted for Tissue Procurement Laboratory. Representative sections are submitted as follows:

- A1: Mirror image of tissue bank
- A2: Tumor with closest parenchymal surgical resection margin, perpendicular section
- A3-A9: Tumor
- A10-A11: Tumor, central scarring area
- A12-A13: Tumor with adjacent liver parenchyma
- A14: Non-tumor liver parenchyma
- A15: Gallbladder

Source: NCI Genomic Data Commons file e5b70951-41a2-4290-8fed-0614f388b214 (TCGA-2Y-A9H8.61B5E3D4-727D-45ED-BAC3-9125A0E03F40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).